Gene-level copy-number profile of tumor specimen HCM-BROD-0106-C71-02A from HCMI case HCM-BROD-0106-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,261 days).
Specimen HCM-BROD-0106-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4ed3536-c2c7-4f87-84bc-5f1dd7660de4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0106-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/87a937b0-f980-4f4e-a990-a3ec453694dd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 39; copy number 2: 7,004; copy number 3: 5,346; copy number 4: 40,691; copy number 5: 3,314; copy number 6: 2,374; copy number 7: 72; copy number 8: 13; copy number 17: 8; copy number 19: 1; copy number 139: 1; copy number 140: 6; copy number 181: 8.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,502,265–20,533,339, 2 genes (within-gene range 0–2): MIR4474, AL163193.1.
- chr9:21,349,835–21,559,900, 15 genes: IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39.
- chr9:21,699,314–21,937,651, 2 genes (within-gene range 0–2): RN7SL151P, MTAP.
- chr9:21,858,910–21,893,857, 2 genes (within-gene range 0–2): AL359922.2, AL359922.3.
- chr9:22,446,824–23,682,662, 9 genes: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:24,542,952–24,545,946, 1 gene: IZUMO3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:35,943,516–36,312,229, 8 genes, copy number 17: SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1.
- chr6:39,048,781–39,091,303, 1 gene, copy number 19: GLP1R.
- chr7:54,419,444–55,344,958, 15 genes, copy number 139–181: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
